Somatic mutation profile of cancer-model specimen HCM-BROD-0097-C15-85B (3D Organoid, passage 9; aliquot HCM-BROD-0097-C15-85B-01D-A78T-36), derived from the metastatic tumor of HCMI case HCM-BROD-0097-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 73.5 years (26,828 days).
Specimen HCM-BROD-0097-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 078ead69-417b-4135-9512-3ef8df3133ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0097-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0097-C15-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30339074-aad1-4515-bb87-5f81ecf8a018

The open-access MAF lists 167 somatic variants for this specimen: 113 protein-altering or splice-affecting, 36 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 36, Nonsense Mutation 5, Intron 5, 3'UTR 3, RNA 3, 5'UTR 3, Splice Region 3, 5'Flank 3, Frame Shift Del 2, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 375/377 reads (99%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TWIST1 | c.350A>T p.E117V | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554442016; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKR1B15 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 315/506 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); catalogued as rs201762103; called by muse, mutect2, varscan2
- ARHGAP5 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV61534215, COSV61539084; called by muse, mutect2, varscan2
- ARL5B | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV66011115; called by muse, mutect2, varscan2
- BORCS6 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 176/567 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV66504784; called by muse, mutect2, varscan2
- CACNA1G | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 65/261 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373767246, COSV61719733; called by muse, mutect2, varscan2
- CCNDBP1 | c.169+4A>G | Splice Region (SNP) | VAF 48/163 reads (29%) | catalogued as rs779646742; called by muse, mutect2, varscan2
- CD2AP | c.1409A>G p.K470R | Missense Mutation (SNP) | VAF 166/387 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs940356500; called by muse, mutect2, varscan2
- CLEC14A | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 133/583 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV60563629; called by muse, mutect2, varscan2
- CNP | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 118/256 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs782146999; called by muse, mutect2, varscan2
- CORO2B | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs144987289, COSV55958776; called by muse, mutect2, varscan2
- DIAPH3 | c.1324C>T p.Q442* (on ENST00000400324 / NM_001042517.2; = p.Q179* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 41/98 reads (42%) | catalogued as COSV57364866; called by muse, mutect2, varscan2
- DNAH10 | c.7489C>T p.R2497W (on ENST00000409039; = p.R2436W on NM_207437.3) | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1311624314; called by muse, mutect2, varscan2
- DPYS | c.1086A>T p.K362N | Missense Mutation (SNP) | VAF 377/1038 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as COSV60907400; called by mutect2, varscan2
- EGR1 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 99/99 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV53520886; called by muse, mutect2, varscan2
- EHBP1 | c.3538G>C p.D1180H | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762739434; called by muse, mutect2, varscan2
- EIF2B5 | c.1819G>A p.V607M (on ENST00000647909; = p.V599M on NM_003907.3) | Missense Mutation (SNP) | VAF 173/609 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1248680116; called by muse, mutect2, varscan2
- ETS1 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 114/618 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60093923; called by muse, mutect2, varscan2
- FBXO24 | c.1429C>G p.L477V (on ENST00000241071 / NM_033506.3; = p.L515V on NM_012172.5) | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV99575023, COSV99575231; called by muse, mutect2, varscan2
- HAUS6 | c.2701G>A p.G901S | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs754329035; called by muse, mutect2, varscan2
- HMCN2 | c.5926C>T p.R1976W | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.535); catalogued as rs577965469; called by muse, mutect2, varscan2
- IFIT2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 161/161 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs757639216; called by muse, mutect2, varscan2
- IGSF9B | c.3104G>A p.R1035H | Missense Mutation (SNP) | VAF 104/579 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.98); catalogued as rs372950944; called by muse, mutect2, varscan2
- KCNF1 | c.678G>C p.E226D | Missense Mutation (SNP) | VAF 164/547 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV54462346; called by muse, mutect2, varscan2
- KIF1C | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 341/342 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as rs147429300; called by muse, mutect2, varscan2
- KRT82 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1224118735; called by muse, mutect2, varscan2
- LDLR | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 113/655 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.762); catalogued as rs768724935, CM0910343; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LPP | c.829C>G p.P277A | Missense Mutation (SNP) | VAF 105/361 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV57087725, COSV57097669; called by muse, mutect2, varscan2
- LRIT1 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 125/238 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs773093905, COSV63895470; called by muse, mutect2, varscan2
- MDGA1 | c.2789C>T p.P930L | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as rs764414730; called by muse, mutect2, varscan2
- MUC16 | c.27217G>C p.E9073Q | Missense Mutation (SNP) | VAF 149/378 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV67457150; called by muse, mutect2, varscan2
- MYO1F | c.2218G>A p.V740I | Missense Mutation (SNP) | VAF 233/1217 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as rs908681220, COSV57794378; called by muse, mutect2, varscan2
- NGEF | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 35/102 reads (34%) | catalogued as COSV99888816; called by muse, mutect2, varscan2
- NRK | c.1009del p.R337Dfs*8 | Frame Shift Del (DEL) | VAF 22/24 reads (92%) | catalogued as rs1336364406; called by mutect2, varscan2
- OR1C1 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs754573857; called by muse, mutect2, varscan2
- OR2A5 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 204/589 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as rs752112825; called by muse, mutect2, varscan2
- OTOP2 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 246/563 reads (44%) | SIFT tolerated (0.86); PolyPhen benign (0.038); catalogued as rs373104376; called by muse, mutect2, varscan2
- PAPPA2 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 201/334 reads (60%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs541683741, COSV62784683; called by muse, mutect2, varscan2
- PCDH9 | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 115/115 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60526324; called by muse, mutect2, varscan2
- PCSK4 | c.1273+4C>T | Splice Region (SNP) | VAF 118/247 reads (48%) | catalogued as rs1184838271; called by muse, mutect2, varscan2
- PCSK6 | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 76/130 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1235099029; called by muse, varscan2
- PHF2 | c.1196C>A p.A399D | Missense Mutation (SNP) | VAF 93/159 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63680343, COSV63680813; called by muse, mutect2, varscan2
- PPM1F | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 88/315 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1003542794, COSV54283631; called by muse, mutect2, varscan2
- PRDM14 | c.1583C>G p.S528C | Missense Mutation (SNP) | VAF 57/495 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770947642, COSV52572727; called by muse, mutect2, varscan2
- PTGDR | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 78/292 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs199602538; called by muse, mutect2, varscan2
- RNF138 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 85/85 reads (100%) | SIFT tolerated (0.49); PolyPhen benign (0.074); catalogued as rs1309524763, COSV99857532; called by muse, mutect2, varscan2
- RPS3A | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs781597345; called by muse, mutect2, varscan2
- RRS1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 92/306 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs759905677; called by muse, mutect2, varscan2
- SCG5 | c.532C>T p.R178* (on ENST00000300175 / NM_001144757.2; = p.R177* on NM_003020.4) | Nonsense Mutation (SNP) | VAF 48/138 reads (35%) | catalogued as rs200799739, COSV55705286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX20 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 130/251 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762125596, COSV56058430; called by muse, mutect2, varscan2
- ST13 | c.224C>G p.S75* | Nonsense Mutation (SNP) | VAF 148/225 reads (66%) | catalogued as COSV53423612; called by muse, mutect2, varscan2
- SYMPK | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 292/584 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs763771090, COSV55616214; called by muse, varscan2
- TCTE1 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 169/353 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV65256016; called by muse, mutect2, varscan2
- UBR5 | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV55279851; called by muse, mutect2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 61/65 reads (94%) | catalogued as rs760213136; called by mutect2, varscan2
- VMP1 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as COSV51864345, COSV99031686; called by muse, mutect2, varscan2
- ZNF175 | c.1877A>G p.Q626R | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1224681203; called by muse, mutect2, varscan2
- ZNF283 | c.1130G>A p.C377Y | Missense Mutation (SNP) | VAF 127/295 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377171671; called by muse, mutect2, varscan2
- ABCB5 | c.2395G>T p.A799S (on ENST00000404938 / NM_001163941.2; = p.A354S on NM_178559.6) | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- AC100868.1 | c.1038C>G p.I346M | Missense Mutation (SNP) | VAF 64/442 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ADGRG6 | c.2582C>T p.T861I | Missense Mutation (SNP) | VAF 87/150 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ARHGAP17 | c.1124T>G p.F375C | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARID3A | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 164/312 reads (53%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- B3GNT2 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 121/417 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CCDC157 | c.1879T>C p.W627R | Missense Mutation (SNP) | VAF 240/392 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, varscan2
- CDK9 | c.7A>G p.K3E | Missense Mutation (SNP) | VAF 121/338 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- COPA | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 70/249 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- DCC | c.2063A>C p.K688T | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DDX42 | c.1484T>G p.F495C | Missense Mutation (SNP) | VAF 281/664 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- EDEM1 | c.1693G>C p.D565H | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EPHA3 | c.1434G>C p.Q478H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- F7 | c.689T>G p.L230W | Missense Mutation (SNP) | VAF 75/266 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FASLG | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 175/571 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FLT3LG | c.481+1G>T p.X161_splice | Splice Site (SNP) | VAF 71/139 reads (51%) | called by muse, mutect2, varscan2
- FPR1 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 211/425 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GABRA6 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 87/189 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- GPRIN1 | c.2704G>A p.A902T | Missense Mutation (SNP) | VAF 161/162 reads (99%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- KLRF2 | c.487G>C p.V163L | Missense Mutation (SNP) | VAF 86/188 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- LAMB4 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 95/354 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYH1 | c.728A>C p.N243T | Missense Mutation (SNP) | VAF 120/389 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- MYH4 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NAV1 | c.4072C>T p.R1358* | Nonsense Mutation (SNP) | VAF 364/587 reads (62%) | called by muse, mutect2, varscan2
- NR2C1 | c.1560G>C p.Q520H | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NUP88 | c.1457C>A p.T486N | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2T10 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- OR2T4 | c.835G>T p.V279L | Missense Mutation (SNP) | VAF 431/661 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PABPC4L | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 94/500 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCSK6 | c.257A>C p.D86A | Missense Mutation (SNP) | VAF 78/131 reads (60%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, varscan2
- PDE8B | c.2624A>G p.K875R | Missense Mutation (SNP) | VAF 270/272 reads (99%) | SIFT tolerated (0.08); PolyPhen benign (0.206); called by mutect2, varscan2
- PHF8 | c.231G>T p.K77N (on ENST00000357988 / NM_001184896.1; = p.K41N on NM_015107.3) | Missense Mutation (SNP) | VAF 234/235 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- PIWIL4 | c.60A>C p.E20D | Missense Mutation (SNP) | VAF 131/252 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB2A | c.91T>C p.F31L | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RAPGEF6 | c.2642C>G p.P881R | Missense Mutation (SNP) | VAF 145/290 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RIMS1 | c.4121G>A p.G1374D | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); called by mutect2, varscan2
- RLBP1 | c.245T>G p.V82G | Missense Mutation (SNP) | VAF 280/488 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ROBO1 | c.4496C>A p.T1499K | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEPTIN8 | c.1140G>C p.E380D | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SFPQ | c.1544C>A p.A515E | Missense Mutation (SNP) | VAF 188/189 reads (99%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SFXN1 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SRCAP | c.8911C>G p.H2971D | Missense Mutation (SNP) | VAF 121/232 reads (52%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBC1D31 | c.986G>C p.S329T | Missense Mutation (SNP) | VAF 88/1224 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2
- TBC1D8B | c.2070A>T p.L690F | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- TNPO2 | c.1558C>G p.L520V | Missense Mutation (SNP) | VAF 80/548 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TP63 | c.100A>G p.S34G | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TPSB2 | c.621C>G p.D207E | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRIM64C | c.1250C>A p.S417Y | Missense Mutation (SNP) | VAF 357/730 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- TSG101 | c.187T>C p.Y63H | Missense Mutation (SNP) | VAF 179/181 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- UGT1A9 | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- UTF1 | c.552C>T p.D184= | Splice Region (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- VCAM1 | c.1977G>C p.Q659H | Missense Mutation (SNP) | VAF 219/400 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZGRF1 | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- ZNF718 | c.452T>G p.V151G | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ADRB1 | c.105C>T p.P35= | Silent (SNP) | VAF 156/293 reads (53%) | catalogued as rs35476499; called by muse, mutect2
- ATP9A | c.2055G>A p.T685= | Silent (SNP) | VAF 59/316 reads (19%) | catalogued as rs781159334; called by muse, mutect2, varscan2
- CGB8 | c.33G>A p.L11= | Silent (SNP) | VAF 178/819 reads (22%) | called by muse, mutect2, varscan2
- COL20A1 | c.2565T>G p.A855= | Silent (SNP) | VAF 67/300 reads (22%) | called by muse, mutect2, varscan2
- CSMD1 | c.6465C>T p.N2155= (on ENST00000520002; = p.N2154= on NM_033225.6) | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as rs766264947, COSV59336661, COSV59366408; called by muse, mutect2, varscan2
- DNAH10 | c.5031G>A p.A1677= (on ENST00000409039; = p.A1616= on NM_207437.3) | Silent (SNP) | VAF 337/664 reads (51%) | catalogued as rs984373122, COSV68993401; called by muse, mutect2, varscan2
- DOCK7 | c.6099G>C p.V2033= (on ENST00000635253 / NM_001367561.1; = p.V2002= on NM_033407.3) | Silent (SNP) | VAF 178/178 reads (100%) | called by muse, mutect2, varscan2
- DYRK1A | c.1575G>A p.G525= | Silent (SNP) | VAF 95/372 reads (26%) | catalogued as rs762621853; called by muse, mutect2, varscan2
- EYS | c.2028G>A p.T676= | Silent (SNP) | VAF 88/468 reads (19%) | catalogued as rs758722034, COSV65515654; called by muse, mutect2, varscan2
- FAM133A | c.483G>A p.K161= | Silent (SNP) | VAF 113/114 reads (99%) | called by muse, mutect2, varscan2
- FAM47B | c.972C>A p.P324= | Silent (SNP) | VAF 29/290 reads (10%) | catalogued as rs1485527852, COSV100264573; called by muse, mutect2, varscan2
- GLYR1 | c.1167G>T p.G389= | Silent (SNP) | VAF 72/496 reads (15%) | called by muse, mutect2, varscan2
- KIAA1109 | c.3375C>T p.N1125= | Silent (SNP) | VAF 83/252 reads (33%) | catalogued as rs766403046; called by muse, varscan2
- KIAA1549 | c.1926G>A p.S642= | Silent (SNP) | VAF 98/152 reads (64%) | catalogued as rs764962649; called by muse, mutect2
- KSR2 | c.1827A>G p.Q609= | Silent (SNP) | VAF 92/194 reads (47%) | catalogued as rs753958451; called by muse, mutect2, varscan2
- LRP1B | c.9723T>C p.H3241= | Silent (SNP) | VAF 68/212 reads (32%) | called by muse, mutect2, varscan2
- MITD1 | c.180T>C p.N60= | Silent (SNP) | VAF 256/352 reads (73%) | called by muse, mutect2, varscan2
- NBR1 | c.1224A>G p.A408= | Silent (SNP) | VAF 104/213 reads (49%) | catalogued as rs762888196; called by muse, mutect2, varscan2
- NOP56 | c.1635T>C p.N545= | Silent (SNP) | VAF 65/496 reads (13%) | catalogued as rs778412263; called by muse, mutect2, varscan2
- NOX4 | c.243T>G p.A81= | Silent (SNP) | VAF 84/355 reads (24%) | catalogued as COSV54463279; called by muse, mutect2, varscan2
- NUDT17 | c.792C>A p.L264= | Silent (SNP) | VAF 137/941 reads (15%) | called by muse, mutect2, varscan2
- OR2L5 | c.201C>T p.L67= | Silent (SNP) | VAF 262/397 reads (66%) | catalogued as COSV62364382; called by muse, mutect2, varscan2
- PATE2 | c.282G>A p.K94= | Silent (SNP) | VAF 48/349 reads (14%) | called by muse, mutect2, varscan2
- PCDH15 | c.2694C>T p.A898= | Silent (SNP) | VAF 188/420 reads (45%) | called by muse, mutect2, varscan2
- PTCD1 | c.504A>G p.R168= | Silent (SNP) | VAF 235/804 reads (29%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.1368G>A p.V456= (on ENST00000265814 / NM_001198628.1; = p.V429= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/341 reads (12%) | catalogued as rs1327825276, COSV99752878; called by muse, mutect2, varscan2
- RYR3 | c.7134T>G p.T2378= (on ENST00000389232; = p.T2379= on NM_001036.6) | Silent (SNP) | VAF 127/423 reads (30%) | catalogued as COSV66778872; called by muse, mutect2, varscan2
- SHANK1 | c.1758C>T p.I586= | Silent (SNP) | VAF 84/341 reads (25%) | catalogued as rs143041573; called by muse, mutect2, varscan2
- SLC6A13 | c.813G>A p.T271= | Silent (SNP) | VAF 166/336 reads (49%) | catalogued as rs147679992, COSV58259322; called by muse, mutect2, varscan2
- TCHH | c.4056G>A p.P1352= | Silent (SNP) | VAF 182/946 reads (19%) | called by mutect2, varscan2
- TMC8 | c.174G>C p.V58= | Silent (SNP) | VAF 81/173 reads (47%) | called by muse, mutect2, varscan2
- TTN | c.39426C>T p.F13142= (on ENST00000591111; = p.F5718= on NM_003319.4) | Silent (SNP) | VAF 70/225 reads (31%) | catalogued as rs367744803; ClinVar: likely benign; called by muse, mutect2, varscan2
- VN1R2 | c.957A>G p.A319= | Silent (SNP) | VAF 45/207 reads (22%) | called by muse, mutect2, varscan2
- ZEB2 | c.1627T>C p.L543= | Silent (SNP) | VAF 68/186 reads (37%) | catalogued as COSV57951463; called by muse, mutect2, varscan2
- ZNF853 | c.724C>T p.L242= | Silent (SNP) | VAF 240/357 reads (67%) | catalogued as rs964259107; called by muse, mutect2, varscan2
- ZSWIM8 | c.2640C>T p.Y880= | Silent (SNP) | VAF 59/216 reads (27%) | called by muse, mutect2, varscan2
- AC009093.3 | chr16:29102126 T>C | 3'Flank (SNP) | VAF 53/615 reads (9%) | called by muse, mutect2
- AC092865.4 | chr12:8390651 T>A | 5'Flank (SNP) | VAF 143/203 reads (70%) | called by muse, varscan2
- ADGRL4 | c.*38T>C | 3'UTR (SNP) | VAF 31/40 reads (78%) | called by muse, mutect2, varscan2
- AOAH | c.128-3332G>C | Intron (SNP) | VAF 86/131 reads (66%) | called by muse, mutect2, varscan2
- AP001496.2 | n.849A>G | RNA (SNP) | VAF 128/527 reads (24%) | called by muse, mutect2, varscan2
- CDC16 | c.-28T>C | 5'UTR (SNP) | VAF 19/20 reads (95%) | called by muse, mutect2, varscan2
- CSRP3 | c.*9G>A | 3'UTR (SNP) | VAF 392/394 reads (99%) | catalogued as rs531722178; called by muse, mutect2, varscan2
- CXADRP2 | n.567A>G | RNA (SNP) | VAF 72/191 reads (38%) | called by muse, mutect2, varscan2
- FAM13A | c.759+45A>T | Intron (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2
- GLT1D1 | c.413-16del | Intron (DEL) | VAF 95/211 reads (45%) | called by mutect2, pindel, varscan2
- PNLIPRP3 | c.-1G>C | 5'UTR (SNP) | VAF 40/212 reads (19%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159917 C>T | 5'Flank (SNP) | VAF 69/137 reads (50%) | catalogued as rs760367787; called by muse, mutect2
- RPL34-DT | n.1113C>A | RNA (SNP) | VAF 172/268 reads (64%) | called by muse, mutect2, varscan2
- SPIDR | c.-10G>A | 5'UTR (SNP) | VAF 10/80 reads (13%) | catalogued as rs1393042772; called by muse, mutect2
- SRGAP3 | c.2558+47C>A | Intron (SNP) | VAF 148/430 reads (34%) | called by muse, mutect2, varscan2
- STARD13 | c.170-18329G>C | Intron (SNP) | VAF 95/595 reads (16%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133568314 G>A | 5'Flank (SNP) | VAF 101/213 reads (47%) | catalogued as COSV58217098; called by muse, mutect2, varscan2
- TAMM41 | c.*38A>T | 3'UTR (SNP) | VAF 43/131 reads (33%) | called by muse, mutect2, varscan2
